Somatic mutation profile of tumor specimen TARGET-10-PAPBAN-09A (aliquot TARGET-10-PAPBAN-09A-01D) from TARGET case TARGET-10-PAPBAN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,816 days).
Specimen TARGET-10-PAPBAN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f925339-bf11-4d6e-957a-94cb7a46a71c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPBAN-14A (Bone Marrow Normal), aliquot TARGET-10-PAPBAN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8ba1a5e-0ee7-40ef-b947-0bbb4d4da952

The open-access MAF lists 45 somatic variants for this specimen: 22 protein-altering or splice-affecting, 15 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 15, Intron 4, RNA 2, Nonsense Mutation 1, Splice Site 1, 3'Flank 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS1 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373807387; called by muse, mutect2, varscan2
- BMP4 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs889958974, COSV55416421; called by muse, mutect2, varscan2
- CA1 | c.451-1G>A p.X151_splice | Splice Site (SNP) | VAF 14/28 reads (50%) | catalogued as COSV56277394; called by muse, mutect2, varscan2
- CBL | c.1103A>G p.Y368C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50663273; called by muse, mutect2, varscan2
- DNAI3 | c.240C>A p.N80K | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV54003415; called by muse, mutect2, varscan2
- DOP1B | c.4097C>T p.S1366L | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs150305493; called by muse, mutect2, varscan2
- MED12L | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56370234, COSV99851498; called by muse, mutect2, varscan2
- OR5I1 | c.473C>T p.S158F | Missense Mutation (SNP) | VAF 51/96 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV56889217; called by muse, mutect2, varscan2
- PDE9A | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as rs1479153246, COSV99371010; called by muse, mutect2, varscan2
- PTPN21 | c.1588C>T p.R530W | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1330630467; called by muse, mutect2, varscan2
- RYR2 | c.5413C>T p.H1805Y | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as rs867966757, COSV63695069; called by muse, mutect2, varscan2
- ZNF804B | c.1642T>A p.F548I | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs1342180710, COSV60820448, COSV60830216; called by muse, mutect2, varscan2
- BHMT2 | c.366G>T p.Q122H | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMC1 | c.418dup p.C140Lfs*21 | Frame Shift Ins (INS) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- FHOD3 | c.2744G>A p.R915K (on ENST00000359247 / NM_001281739.3; = p.R932K on NM_025135.5) | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HSPG2 | c.5774C>T p.P1925L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- ITGAV | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LY6G5B | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PDCD10 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- PHF13 | c.900C>G p.D300E | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PM20D1 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF385B | c.1248A>T p.K416N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AKR1C4 | c.519G>A p.L173= | Silent (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
- CLCN2 | c.1158C>T p.F386= | Silent (SNP) | VAF 19/69 reads (28%) | called by muse, mutect2, varscan2
- COL3A1 | c.3399A>T p.P1133= | Silent (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- DMC1 | c.417C>T p.L139= | Silent (SNP) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- HIVEP1 | c.1965C>T p.S655= | Silent (SNP) | VAF 38/106 reads (36%) | called by muse, mutect2, varscan2
- KLHDC9 | c.624C>T p.L208= | Silent (SNP) | VAF 46/107 reads (43%) | called by muse, mutect2, varscan2
- LDB2 | c.1005C>T p.D335= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs749480922; called by muse, mutect2, varscan2
- MECOM | c.1971G>A p.E657= (on ENST00000468789 / NM_001105078.4; = p.E845= on NM_004991.4) | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs1560174849; called by muse, mutect2, varscan2
- OR6K2 | c.99C>T p.F33= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV62743220; called by muse, mutect2, varscan2
- OSBPL8 | c.1476C>T p.F492= | Silent (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- PNLIPRP2 | c.66C>T p.Y22= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as rs372333536; called by muse, mutect2, varscan2
- TLR3 | c.2592C>T p.L864= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs200609786; called by muse, mutect2, varscan2
- TLR7 | c.2079G>A p.K693= | Silent (SNP) | VAF 67/212 reads (32%) | called by muse, mutect2, varscan2
- TP53BP1 | c.3981T>C p.S1327= | Silent (SNP) | VAF 43/93 reads (46%) | catalogued as rs575885085; called by muse, mutect2, varscan2
- TRAPPC9 | c.1434C>T p.A478= | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as rs551910305; called by muse, mutect2, varscan2
- C10orf88B | n.382C>T | RNA (SNP) | VAF 41/128 reads (32%) | catalogued as rs761687980; called by muse, mutect2, varscan2
- CROCC2 | c.4558-2712C>T | Intron (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- FGD2 | c.1752+24C>T | Intron (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- GCOM1 | c.1119+6769G>A | Intron (SNP) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- MEIS3P2 | n.687T>A | RNA (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- POTEC | chr18:14511850 C>T | 3'Flank (SNP) | VAF 27/97 reads (28%) | catalogued as rs866111881; called by muse, mutect2, varscan2
- TRIM29 | c.1627+1289C>G | Intron (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- TSHZ2 | c.*2036G>A | 3'UTR (SNP) | VAF 49/91 reads (54%) | called by muse, mutect2, varscan2
